Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A7EL, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A7EL-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

[REDACTED]

....

Clinical Diagnosis & History:

[REDACTED] with leiomyosarcoma IVC.

Specimens Submitted:

1: SP: Inferior IVC leiomyosarcoma

DIAGNOSIS:

- 1) SOFT TISSUE, INFERIOR IVC TUMOR; EXCISION:
- HIGH GRADE LEIOMYOSARCOMA.
- TUMOR MEASURES 7.0 CM GREATEST DIMENSION, INVOLVES FIBROADIPOSE TISSUE AND THE WALL OF A LARGE VEIN, SHOWS ABOUT 10% NECROSIS, AND FOCALLY COMES WITHIN 0.02 CM OF UNDESIGNATED INKED MARGIN.
- TWO BENIGN LYMPH NODES.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

ICD-O-3
Leiomyosarcoma NOS
8890/3
Site Retroperitoneum
C48.0
JW 9/26/13

1). The specimen is received fresh labeled, "inferior IVC leiomyosarcoma", and consists of a 7.0 x 5.5 x 5.0 cm lobulated white mass covered entirely by a thin, shiny membrane. A pedunculated fragment of fibroadipose tissue measuring 7.0 x 1.1 x 0.5 cm is attached to the mass. The specimen is not oriented and inked entirely black. Serial sections reveal pink to white whorled surfaces with focal myxoid change, but no obvious necrosis or hemorrhage. Photographs are taken. TPS is submitted. Representative sections are submitted.

Summary of sections:

** Continued on next page **

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

U -- undesignated

Page 2 of 2

Summary of Sections:

Part 1: SP: Inferior IVC leiomyosarcoma

Block	Sect. Site	PCs
8	U	8

** End of Report **

Source: NCI Genomic Data Commons file 2e81cba3-5ac9-40d6-a852-e84575f8fd88 (TCGA-DX-A7EL.C68569C1-2FBC-4E05-91C2-6B28551675A4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).